Somatic mutation profile of tumor specimen TCGA-EM-A22M-01A (aliquot TCGA-EM-A22M-01A-11D-A17V-08) from TCGA case TCGA-EM-A22M, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 52.2 years (19,059 days).
Specimen TCGA-EM-A22M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4af09dc4-8ca5-483c-8525-34b560830803.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22M-10A (Blood Derived Normal), aliquot TCGA-EM-A22M-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3392729-3893-42c9-9bf0-a449407a5457

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AP5B1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs771359788, COSV100376131; called by muse, mutect2, varscan2
- FAM155A | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65591079; called by muse, mutect2, varscan2
- NECTIN1 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99872511; called by muse, mutect2
- NUDT8 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV56875106; called by muse, mutect2, varscan2
- TTC12 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV59098394; called by muse, mutect2, varscan2
- TTF2 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101037743; called by muse, mutect2, varscan2
- ZNF226 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100335221; called by muse, mutect2
- ZNF43 | c.2112A>C p.K704N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100731918; called by muse, mutect2, varscan2
- GRXCR1 | c.214del p.E72Rfs*12 | Frame Shift Del (DEL) | VAF 27/138 reads (20%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.1125A>G p.P375= | Silent (SNP) | VAF 43/283 reads (15%) | catalogued as COSV100519387; called by muse, mutect2, varscan2
- ZNF559 | c.735A>G p.A245= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100416663; called by muse, mutect2, varscan2
